Somatic mutation profile of tumor specimen 0DNWKU from CCDI case PBCBWD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.8 years (1,380 days).
Specimen 0DNWKU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 450685f0-5934-4de3-a8e8-9b91d26b4497.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNWJH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78add359-36af-4466-b07f-f56f683effeb

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, RNA 1, Silent 1, Splice Site 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GOLGA1 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 185/366 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138234842, COSV100332316; called by muse, mutect2, varscan2
- MUC3A | c.2396C>T p.T799M | Missense Mutation (SNP) | VAF 124/452 reads (27%) | SIFT tolerated, low confidence (0.13); catalogued as rs1038277968; called by muse, varscan2
- ZNF408 | c.1346G>A p.R449Q | Missense Mutation (SNP) | VAF 21/298 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs376401300; called by muse, mutect2
- ANKRD26 | c.3614A>C p.E1205A | Missense Mutation (SNP) | VAF 71/191 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PTPDC1 | c.2048A>G p.Q683R (on ENST00000375360 / NM_177995.3; = p.Q735R on NM_152422.4) | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- SLC24A3 | c.1607-1G>T p.X536_splice | Splice Site (SNP) | VAF 64/126 reads (51%) | called by muse, mutect2, varscan2
- MBD3L5 | c.30G>A p.P10= | Silent (SNP) | VAF 39/321 reads (12%) | catalogued as rs1314006731; called by muse, mutect2
- AP003027.1 | n.1021G>A | RNA (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- GPM6B | c.-38C>G | 5'UTR (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2
- THOC5 | c.1798-64T>A | Intron (SNP) | VAF 44/91 reads (48%) | called by muse, mutect2, varscan2
